Somatic mutation profile of tumor specimen TCGA-AO-A03P-01A (aliquot TCGA-AO-A03P-01A-11W-A019-09) from TCGA case TCGA-AO-A03P, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 54.0 years (19,724 days).
Specimen TCGA-AO-A03P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c41e58e3-b2ee-4695-91d0-f993ced4e77b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A03P-10A (Blood Derived Normal), aliquot TCGA-AO-A03P-10A-01W-A021-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8465f55f-163d-4b91-b609-a2f2209afa43

The open-access MAF lists 47 somatic variants for this specimen: 33 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 25, Silent 14, Splice Site 2, Frame Shift Del 2, Frame Shift Ins 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.4551A>T p.L1517F | Missense Mutation (SNP) | VAF 95/199 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV99685258; called by muse, mutect2, varscan2
- ARL5A | c.286A>G p.R96G | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV54470105; called by muse, mutect2, varscan2
- BCAP31 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs1557047947, COSV61452492; called by muse, mutect2
- CAPN10 | c.1061G>C p.G354A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54376194; called by muse, mutect2, varscan2
- DDX21 | c.1756G>A p.V586M | Missense Mutation (SNP) | VAF 111/452 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as rs1169491008, COSV62555641; called by muse, mutect2, varscan2
- EDAR | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as rs369409048, COSV51501997; called by muse, mutect2
- ERBIN | c.1921_1922del p.D641Ffs*5 | Frame Shift Del (DEL) | VAF 38/234 reads (16%) | catalogued as rs1168815964; called by mutect2, pindel, varscan2
- GPX5 | c.489G>T p.L163F | Missense Mutation (SNP) | VAF 168/768 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV69079329; called by muse, mutect2, varscan2
- HCFC1 | c.3083C>A p.T1028K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV60069996, COSV60071808; called by mutect2, varscan2
- HOMER2 | c.568C>T p.L190F (on ENST00000304231 / NM_199330.3; = p.L179F on NM_004839.4) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs752308964, COSV58485782; called by muse, mutect2, varscan2
- IARS1 | c.2864C>G p.T955R | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV65113013; called by muse, mutect2, varscan2
- ITGA7 | c.1597G>A p.D533N (on ENST00000555728; = p.D489N on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as rs1318351319, COSV57694738, COSV57697599; called by muse, mutect2, varscan2
- KIF4A | c.905G>C p.G302A | Missense Mutation (SNP) | VAF 81/396 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV65542856; called by muse, mutect2, varscan2
- KRT25 | c.466C>A p.L156M | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56444598; called by muse, mutect2, varscan2
- MFSD8 | c.1156C>T p.L386F | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV56551080; called by muse, mutect2, varscan2
- MVP | c.747G>A p.W249* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as rs926674606, COSV62421972; called by muse, mutect2, varscan2
- NLRC4 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs747147167, COSV61592382; called by muse, mutect2, varscan2
- OBSCN | c.10526G>T p.G3509V | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV52769437; called by muse, mutect2, varscan2
- PPM1E | c.1105C>G p.P369A | Missense Mutation (SNP) | VAF 53/253 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57573501; called by muse, mutect2, varscan2
- PRRC2B | c.1955C>A p.P652Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV61936522, COSV61945812; called by muse, mutect2, varscan2
- PRSS12 | c.2450G>A p.R817H | Missense Mutation (SNP) | VAF 114/497 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs980368947, COSV56605817; called by muse, mutect2, varscan2
- QARS1 | c.494T>G p.I165S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV60274815; called by muse, mutect2, varscan2
- RAP2A | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV55354928; called by muse, mutect2, varscan2
- SLC20A1 | c.1333A>C p.M445L | Missense Mutation (SNP) | VAF 64/303 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV55611096; called by muse, mutect2, varscan2
- SPTB | c.3622C>T p.R1208W | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs374240422; called by muse, mutect2, varscan2
- TREM1 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs775893448, COSV55148143; called by muse, mutect2, varscan2
- TUT7 | c.2707G>A p.A903T | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52895366; called by muse, mutect2, varscan2
- UTRN | c.5541+1G>T p.X1847_splice | Splice Site (SNP) | VAF 18/121 reads (15%) | catalogued as COSV62334043; called by muse, mutect2, varscan2
- CDHR3 | c.1253del p.P418Qfs*4 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | called by mutect2, pindel, varscan2
- ERCC6L2 | c.3736C>T p.H1246Y | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by mutect2, varscan2
- GATA3 | c.1325dup p.M442Ifs*65 | Frame Shift Ins (INS) | VAF 32/110 reads (29%) | called by mutect2, pindel, varscan2
- RAB5C | c.202dup p.T68Nfs*6 | Frame Shift Ins (INS) | VAF 34/214 reads (16%) | called by mutect2, pindel, varscan2
- SRPRB | c.148_154+13del p.X50_splice | Splice Site (DEL) | VAF 10/18 reads (56%) | called by mutect2, varscan2
- AMY2B | c.138T>C p.Y46= | Silent (SNP) | VAF 114/413 reads (28%) | catalogued as COSV63715111; called by muse, mutect2, varscan2
- DIO1 | c.426C>T p.D142= | Silent (SNP) | VAF 73/227 reads (32%) | catalogued as COSV59517816; called by muse, mutect2, varscan2
- GALNTL6 | c.1761T>A p.I587= | Silent (SNP) | VAF 87/449 reads (19%) | catalogued as COSV72490714; called by muse, mutect2, varscan2
- ITGB5 | c.1977C>T p.S659= | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as COSV56148644; called by muse, mutect2, varscan2
- MDM1 | c.264C>T p.A88= | Silent (SNP) | VAF 40/228 reads (18%) | catalogued as COSV57445678; called by muse, mutect2, varscan2
- OR5K3 | c.732C>A p.L244= | Silent (SNP) | VAF 178/753 reads (24%) | catalogued as COSV67349951; called by muse, mutect2, varscan2
- PRDM11 | c.927G>A p.V309= (on ENST00000530656 / NM_001359633.1; = p.V275= on NM_001256695.1) | Silent (SNP) | VAF 63/341 reads (18%) | catalogued as COSV55439582; called by muse, mutect2, varscan2
- PRKACG | c.210C>T p.Y70= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs141391648; called by muse, mutect2, varscan2
- RYR3 | c.12459C>T p.T4153= (on ENST00000389232; = p.T4154= on NM_001036.6) | Silent (SNP) | VAF 55/191 reads (29%) | catalogued as rs756142838, COSV66786520; called by muse, mutect2, varscan2
- SEC61B | c.288G>A p.S96= | Silent (SNP) | VAF 46/250 reads (18%) | catalogued as rs113789599; called by muse, mutect2, varscan2
- SLC6A5 | c.1566C>T p.S522= | Silent (SNP) | VAF 71/109 reads (65%) | catalogued as rs762275099, COSV54225937; called by muse, mutect2, varscan2
- SLITRK2 | c.444C>T p.A148= | Silent (SNP) | VAF 5/94 reads (5%) | catalogued as rs782649137, COSV100157552; called by muse, mutect2
- SMAD1 | c.1209C>T p.V403= | Silent (SNP) | VAF 96/427 reads (22%) | catalogued as COSV57471079; called by muse, mutect2, varscan2
- TM7SF2 | c.1111C>T p.L371= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV54204820; called by muse, mutect2, varscan2
